Somatic mutation profile of tumor specimen TCGA-73-4662-01A (aliquot TCGA-73-4662-01A-01D-1265-08) from TCGA case TCGA-73-4662, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 65.1 years (23,762 days).
Specimen TCGA-73-4662-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ede6b4a7-aa1d-4324-b91e-d842f7f7cdc6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-73-4662-11A (Solid Tissue Normal), aliquot TCGA-73-4662-11A-01D-1265-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a7e41e8a-57ac-4206-a300-ce3377059e5a

The open-access MAF lists 222 somatic variants for this specimen: 173 protein-altering or splice-affecting, 43 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 149, Silent 43, Nonsense Mutation 9, Intron 5, Splice Site 5, Frame Shift Del 4, In Frame Del 2, Splice Region 2, 3'UTR 1, Frame Shift Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 9/22 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AASDH | c.1577-1G>A p.X526_splice | Splice Site (SNP) | VAF 13/33 reads (39%) | catalogued as COSV52709053; called by muse, varscan2
- ADD2 | c.1188T>A p.S396R | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.214); catalogued as COSV52467382; called by muse, mutect2, varscan2
- ADGRB2 | c.3774G>T p.E1258D | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV57077126; called by muse, mutect2, varscan2
- ADGRF4 | c.1248G>T p.L416F | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51955601; called by muse, mutect2, varscan2
- ADORA1 | c.643G>C p.V215L | Missense Mutation (SNP) | VAF 30/197 reads (15%) | SIFT tolerated (0.79); PolyPhen benign (0.005); catalogued as rs1314427155, COSV55143664; called by muse, mutect2, varscan2
- AFF2 | c.2927C>A p.P976Q | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.998); catalogued as COSV54000982; called by muse, mutect2, varscan2
- AHNAK2 | c.9762C>A p.D3254E | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.612); catalogued as COSV60915319, COSV60924656; called by muse, mutect2
- AHNAK2 | c.9267C>A p.D3089E | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.192); catalogued as COSV60915324, COSV60924663; called by muse, mutect2
- ALPI | c.962A>G p.N321S | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV55015682; called by muse, mutect2, varscan2
- AMOT | c.2329G>T p.E777* (on ENST00000371959 / NM_001113490.1; = p.E368* on NM_133265.3) | Nonsense Mutation (SNP) | VAF 184/435 reads (42%) | catalogued as COSV59066797; called by muse, mutect2, varscan2
- ANK2 | c.3338C>A p.T1113N | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.755); catalogued as COSV52179100; called by muse, mutect2, varscan2
- ARHGEF37 | c.1715G>A p.S572N | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV61369768; called by muse, mutect2, varscan2
- ARMC3 | c.1963T>A p.S655T | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.551); catalogued as rs1564392076, COSV53065441; called by muse, mutect2, varscan2
- ATAD2B | c.4009T>A p.C1337S | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV53203518; called by muse, mutect2, varscan2
- ATP10D | c.2716A>T p.I906L | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV56711203; called by muse, mutect2, varscan2
- ATP2C1 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs771867563, COSV60760648; called by muse, mutect2, varscan2
- BCL10 | c.256A>G p.I86V | Missense Mutation (SNP) | VAF 21/207 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); catalogued as rs1346396823, COSV100997775, COSV100997819; called by muse, mutect2, varscan2
- BNC2 | c.845T>A p.I282K | Missense Mutation (SNP) | VAF 16/173 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66153790; called by muse, mutect2
- BRCA2 | c.1661G>T p.C554F | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as rs748215651, COSV66459524; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRWD3 | c.4982G>C p.G1661A | Missense Mutation (SNP) | VAF 15/339 reads (4%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); catalogued as rs1341767014, COSV64748225, COSV64751991; called by muse, mutect2
- BRWD3 | c.4227G>T p.K1409N | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV64751998; called by muse, mutect2, varscan2
- BTK | c.1035C>A p.Y345* | Nonsense Mutation (SNP) | VAF 64/332 reads (19%) | catalogued as COSV58122643; called by muse, mutect2, varscan2
- C2CD2 | c.1639G>T p.A547S | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as rs567596181, COSV100297959, COSV61600211; called by muse, mutect2, varscan2
- CCDC170 | c.589-1G>T p.X197_splice | Splice Site (SNP) | VAF 19/50 reads (38%) | catalogued as COSV53344329; called by muse, mutect2, varscan2
- CCDC88A | c.2160G>T p.M720I | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV55067307; called by muse, mutect2, varscan2
- CDH7 | c.362G>T p.R121L | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.448); catalogued as COSV59884783, COSV59891309; called by muse, mutect2, varscan2
- CDYL | c.592G>T p.V198L (on ENST00000328908 / NM_001368125.1; = p.V144L on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.247); catalogued as COSV59361094, COSV59361201; called by muse, mutect2, varscan2
- CENPI | c.2056C>A p.P686T | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV99515691; called by muse, mutect2, varscan2
- CENPI | c.2057C>A p.P686H | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99515693; called by muse, mutect2, varscan2
- CHIT1 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as COSV55148814; called by muse, mutect2, varscan2
- CHRM4 | c.1061T>A p.V354E | Missense Mutation (SNP) | VAF 26/175 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.425); catalogued as COSV100642108; called by muse, mutect2, varscan2
- CLEC4F | c.855C>G p.I285M | Missense Mutation (SNP) | VAF 63/191 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.026); catalogued as COSV55480715; called by muse, mutect2, varscan2
- CNDP1 | c.455C>T p.T152M | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as rs533342778, COSV62594795; called by muse, mutect2, varscan2
- CNOT6 | c.1072G>T p.A358S | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.241); catalogued as COSV56163345; called by muse, mutect2, varscan2
- COL3A1 | c.3692C>A p.T1231N | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.462); catalogued as COSV58594139; called by muse, mutect2, varscan2
- COL6A3 | c.9394C>T p.P3132S | Missense Mutation (SNP) | VAF 24/185 reads (13%) | SIFT tolerated (0.92); PolyPhen benign (0.005); catalogued as rs147533489; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CPXCR1 | c.135A>T p.E45D | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as COSV52163954; called by muse, mutect2
- CROCC | c.4505T>C p.L1502P | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV65014100; called by muse, mutect2, varscan2
- CTDSPL2 | c.980G>C p.R327T | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV52947540; called by muse, mutect2, varscan2
- DBR1 | c.1003C>T p.L335F | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.665); catalogued as COSV53430765; called by muse, mutect2, varscan2
- DNAH11 | c.6500G>T p.R2167L | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV60968606, COSV60971874; called by muse, mutect2, varscan2
- DYNC2LI1 | c.640G>C p.G214R | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99571429; called by muse, mutect2, varscan2
- DYNC2LI1 | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99571436; called by muse, mutect2, varscan2
- E2F7 | c.1432G>C p.D478H | Missense Mutation (SNP) | VAF 66/220 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.274); catalogued as COSV59742307; called by muse, mutect2, varscan2
- ECM1 | c.1208C>T p.P403L | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748210541, COSV60874302; called by muse, mutect2, varscan2
- EHF | c.311T>C p.L104P | Missense Mutation (SNP) | VAF 65/221 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57669421; called by muse, varscan2
- ENTPD6 | c.887G>T p.G296V | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61752152; called by muse, mutect2, varscan2
- EPB41L5 | c.1127C>G p.S376C | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55355613; called by muse, mutect2, varscan2
- EPC1 | c.1415C>T p.S472L | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV53928541; called by muse, mutect2, varscan2
- EPHA6 | c.2623G>A p.G875S (on ENST00000389672 / NM_001080448.3; = p.G267S on NM_173655.4) | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67587014; called by muse, mutect2, varscan2
- ERBB3 | c.1912G>T p.G638C | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as rs1200363001, COSV57259743, COSV57262130; called by muse, mutect2, varscan2
- ESRRG | c.469C>T p.Q157* | Nonsense Mutation (SNP) | VAF 17/100 reads (17%) | catalogued as COSV63173879; called by muse, varscan2
- EYS | c.1357C>A p.L453I | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.108); catalogued as COSV60983019, COSV60995980; called by muse, mutect2, varscan2
- FBLN2 | c.1763T>A p.L588Q | Missense Mutation (SNP) | VAF 53/145 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55488976; called by muse, mutect2, varscan2
- FLG | c.1313C>T p.S438L | Missense Mutation (SNP) | VAF 121/520 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV64245862; called by muse, mutect2, varscan2
- FMNL3 | c.1564C>T p.P522S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.9); catalogued as COSV53300905, COSV53305839; called by muse, mutect2, varscan2
- FZR1 | c.149C>A p.P50H | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58051939, COSV58053010; called by muse, mutect2, varscan2
- GAA | c.461G>T p.R154L | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.139); catalogued as CD085127, CM081268, COSV56410851; called by muse, mutect2, varscan2
- GABRA6 | c.1258T>G p.Y420D | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV50888711; called by muse, mutect2, varscan2
- GABRB1 | c.1018G>C p.G340R | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.153); catalogued as COSV54993973; called by muse, mutect2, varscan2
- GATA3 | c.922-1G>T p.X308_splice | Splice Site (SNP) | VAF 8/100 reads (8%) | catalogued as COSV60521297; called by muse, mutect2
- GJD2 | c.577G>T p.E193* | Nonsense Mutation (SNP) | VAF 68/142 reads (48%) | catalogued as COSV51747480, COSV51749580; called by mutect2, varscan2
- GPR143 | c.1127A>G p.D376G | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as COSV66632900; called by muse, mutect2, varscan2
- GRM1 | c.1336G>T p.D446Y | Missense Mutation (SNP) | VAF 60/178 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51232380; called by muse, mutect2, varscan2
- HELZ | c.5440C>G p.Q1814E | Missense Mutation (SNP) | VAF 31/204 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.073); catalogued as COSV62380043, COSV62380058; called by muse, mutect2, varscan2
- HEY2 | c.990G>T p.W330C | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV64239873; called by muse, mutect2, varscan2
- HS3ST5 | c.221G>T p.G74V | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.792); catalogued as COSV100450931, COSV57147634; called by muse, mutect2, varscan2
- HYDIN | c.11654G>T p.G3885V | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV66641222; called by muse, mutect2, varscan2
- IFT81 | c.725G>A p.R242K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.671); catalogued as COSV54362353, COSV54365382; called by muse, mutect2, varscan2
- IGDCC3 | c.2018T>C p.V673A | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.232); catalogued as COSV60079236; called by muse, mutect2, varscan2
- IGSF1 | c.5C>A p.T2N | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as rs745905665, COSV100812217; called by muse, mutect2, varscan2
- IMP4 | c.593G>C p.R198P | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52091192, COSV99383626, COSV99383804; called by muse, mutect2, varscan2
- ITIH5 | c.1465G>A p.D489N | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.043); catalogued as rs887329530, COSV53670082; called by muse, mutect2, varscan2
- KANK4 | c.557C>A p.A186D | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as rs778663710, COSV100587572, COSV62988416; called by muse, mutect2, varscan2
- KCNB2 | c.451G>C p.E151Q | Missense Mutation (SNP) | VAF 63/198 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV73050512; called by muse, mutect2, varscan2
- KCNH1 | c.1003C>G p.P335A | Missense Mutation (SNP) | VAF 12/269 reads (4%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV55095246; called by muse, mutect2
- KIF27 | c.2074G>C p.E692Q | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV52830188, COSV52832633; called by muse, mutect2, varscan2
- KRT17 | c.602G>T p.R201I | Missense Mutation (SNP) | VAF 70/185 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV60861607; called by muse, mutect2, varscan2
- LAMA1 | c.5171C>A p.A1724D | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as rs746164036, COSV67541676; called by muse, mutect2, varscan2
- LAMA5 | c.805C>A p.L269M | Missense Mutation (SNP) | VAF 22/31 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53367931; called by muse, mutect2, varscan2
- LCE2D | c.235C>G p.R79G | Missense Mutation (SNP) | VAF 90/173 reads (52%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs544222876, COSV100909563; called by muse, mutect2, varscan2
- LILRB2 | c.1151G>A p.S384N | Missense Mutation (SNP) | VAF 30/177 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.396); catalogued as rs1363001822, COSV58747451; called by muse, mutect2, varscan2
- LRP1B | c.800C>A p.A267E | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV67256684; called by muse, mutect2, varscan2
- LRRC7 | c.299C>A p.P100H (on ENST00000651989 / NM_001370785.2; = p.P67H on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50551795; called by muse, mutect2, varscan2
- MAGEA4 | c.227T>A p.I76N | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV99367647; called by muse, mutect2, varscan2
- MAP3K19 | c.1249T>A p.S417T | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as COSV59641140; called by muse, mutect2, varscan2
- MARCHF6 | c.1895G>A p.R632K | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as COSV56884970; called by muse, mutect2, varscan2
- MARK1 | c.709G>T p.E237* | Nonsense Mutation (SNP) | VAF 23/56 reads (41%) | catalogued as COSV65070129; called by muse, mutect2, varscan2
- MBD1 | c.1090G>T p.G364C (on ENST00000269468 / NM_001323950.1; = p.G341C on NM_015845.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54005193; called by muse, mutect2, varscan2
- MCM3AP | c.5879C>T p.S1960L | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV52443874; called by muse, mutect2, varscan2
- MLLT10 | c.2612A>G p.N871S (on ENST00000307729 / NM_001195626.3; = p.N887S on NM_004641.3) | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as rs766742114, COSV57001721; called by muse, mutect2, varscan2
- MPHOSPH8 | c.1190G>T p.G397V | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV64056999; called by muse, mutect2, varscan2
- MUC16 | c.20865G>C p.E6955D | Missense Mutation (SNP) | VAF 18/227 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV67482334; called by muse, mutect2
- MYLK3 | c.1498C>G p.R500G | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV67362833, COSV67365893; called by muse, mutect2, varscan2
- MYRF | c.1702G>T p.D568Y (on ENST00000278836 / NM_001127392.3; = p.D559Y on NM_013279.4) | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV53892230; called by muse, mutect2, varscan2
- NLRP5 | c.2004G>T p.W668C | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.609); catalogued as COSV66766516, COSV66768034; called by muse, mutect2, varscan2
- NSDHL | c.665G>T p.G222V | Missense Mutation (SNP) | VAF 24/226 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64744870; called by muse, mutect2
- OR13C4 | c.799C>A p.L267I | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.01); catalogued as COSV52927909; called by muse, mutect2, varscan2
- OR2G3 | c.210C>A p.D70E | Missense Mutation (SNP) | VAF 102/540 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV60682561; called by muse, mutect2, varscan2
- OR2M4 | c.632T>G p.V211G | Missense Mutation (SNP) | VAF 6/139 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV60709184; called by muse, mutect2
- OR4S1 | c.680C>A p.S227* | Nonsense Mutation (SNP) | VAF 52/236 reads (22%) | catalogued as rs778079725, COSV100180304; called by muse, mutect2, varscan2
- OR4X1 | c.188A>G p.Y63C | Missense Mutation (SNP) | VAF 5/104 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV60723525; called by muse, mutect2
- OR51A7 | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63788772; called by muse, mutect2, varscan2
- OR56A4 | c.743C>T p.T248I | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.069); catalogued as COSV58111324; called by muse, mutect2, varscan2
- OR8J1 | c.291T>A p.C97* | Nonsense Mutation (SNP) | VAF 32/139 reads (23%) | catalogued as COSV57319497; called by muse, mutect2, varscan2
- PAPOLB | c.1351G>T p.E451* | Nonsense Mutation (SNP) | VAF 74/180 reads (41%) | catalogued as COSV68202784; called by muse, mutect2
- PCDHA10 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56532848; called by muse, mutect2, varscan2
- PCDHB7 | c.2214C>G p.S738R | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.134); catalogued as rs782200287, COSV50758039, COSV50800092; called by muse, mutect2, varscan2
- PCDHGA2 | c.1770G>T p.K590N | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs749012008, COSV54002597; called by muse, mutect2, varscan2
- PDE11A | c.957G>T p.K319N | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV53703768; called by muse, mutect2
- PI4KB | c.1079A>G p.N360S (on ENST00000368873 / NM_001369623.1; = p.N372S on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1167441613, COSV55014848; called by muse, varscan2
- PIWIL1 | c.1468G>T p.V490F | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.429); catalogued as COSV55350204; called by muse, mutect2, varscan2
- PLXNA3 | c.3127G>C p.V1043L | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63755063; called by muse, mutect2, varscan2
- PMFBP1 | c.2224A>C p.K742Q (on ENST00000537465; = p.K737Q on NM_031293.3) | Missense Mutation (SNP) | VAF 74/170 reads (44%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.994); catalogued as COSV52829484; called by muse, mutect2, varscan2
- PRAME | c.305A>T p.D102V | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV67162264; called by muse, mutect2, varscan2
- PRDM10 | c.1795C>T p.R599C | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs772208700, COSV58800419; called by muse, mutect2, varscan2
- PRPF19 | c.1427G>A p.G476D | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV57128897; called by muse, mutect2, varscan2
- PSIP1 | c.929A>C p.E310A | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs200120477; called by muse, mutect2, varscan2
- PSME4 | c.4092A>T p.L1364F | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV66366800; called by muse, mutect2, varscan2
- PTCH1 | c.4306G>T p.E1436* | Nonsense Mutation (SNP) | VAF 53/139 reads (38%) | catalogued as COSV59487366; called by muse, mutect2, varscan2
- PTPRS | c.5386G>T p.A1796S | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.99); catalogued as COSV53631265; called by muse, mutect2, varscan2
- RAB9B | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 38/213 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV54588092; called by muse, mutect2, varscan2
- RAPGEF2 | c.4037G>T p.R1346L | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.901); catalogued as COSV52432008; called by muse, mutect2, varscan2
- RBMX | c.302G>T p.R101I | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as COSV100284874; called by muse, mutect2, varscan2
- RHOXF1 | c.187G>T p.D63Y | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV54295416; called by muse, mutect2, varscan2
- RNF32 | c.832T>A p.W278R | Missense Mutation (SNP) | VAF 55/104 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100311552; called by muse, mutect2, varscan2
- SKI | c.1148C>T p.S383F | Missense Mutation (SNP) | VAF 88/269 reads (33%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.994); catalogued as COSV66014313; called by muse, mutect2, varscan2
- SLC24A2 | c.1350C>A p.T450= | Splice Region (SNP) | VAF 16/105 reads (15%) | catalogued as rs375331527, COSV53871724; called by muse, mutect2
- SPIC | c.223del p.D75Tfs*15 | Frame Shift Del (DEL) | VAF 36/245 reads (15%) | catalogued as COSV100162850, COSV54690572; called by mutect2, pindel, varscan2
- SPTA1 | c.5599G>C p.D1867H | Missense Mutation (SNP) | VAF 92/195 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63757415; called by muse, mutect2, varscan2
- STAU1 | c.277G>T p.V93F (on ENST00000371856 / NM_001319135.1; = p.V12F on NM_004602.3) | Missense Mutation (SNP) | VAF 74/127 reads (58%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.616); catalogued as COSV61461766; called by muse, mutect2, varscan2
- STYXL2 | c.2701C>A p.R901S | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as COSV54801903, COSV54808539; called by muse, mutect2, varscan2
- SVEP1 | c.1316C>T p.P439L | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV57043785; called by muse, mutect2, varscan2
- SYT10 | c.1508G>C p.G503A | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as COSV57343639; called by muse, mutect2, varscan2
- TAGLN2 | c.572G>T p.G191V | Missense Mutation (SNP) | VAF 53/207 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV100231158, COSV100231252; called by muse, mutect2, varscan2
- TAGLN2 | c.571G>T p.G191C | Missense Mutation (SNP) | VAF 52/207 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.236); catalogued as COSV100231254; called by muse, mutect2, varscan2
- TAGLN3 | c.125T>C p.I42T | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs1199260399, COSV56328896; called by muse, mutect2, varscan2
- TBC1D12 | c.2142G>A p.M714I | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV56556799; called by muse, mutect2, varscan2
- TBX15 | c.623C>A p.T208N (on ENST00000369429 / NM_001330677.2; = p.T102N on NM_152380.3) | Missense Mutation (SNP) | VAF 74/154 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV52874540; called by muse, mutect2, varscan2
- TBX3 | c.307C>A p.P103T | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57474224; called by muse, mutect2, varscan2
- TFB2M | c.740A>G p.Y247C | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63625081; called by muse, mutect2, varscan2
- THSD7A | c.2419C>A p.P807T | Missense Mutation (SNP) | VAF 58/163 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.826); catalogued as COSV70269861; called by muse, mutect2, varscan2
- TIAM1 | c.659C>A p.P220Q | Missense Mutation (SNP) | VAF 59/110 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.186); catalogued as COSV54552619, COSV54566152; called by muse, mutect2, varscan2
- TIGIT | c.249T>A p.D83E | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67329256; called by muse, mutect2, varscan2
- TLN1 | c.4289C>T p.S1430L | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV59210367; called by muse, mutect2, varscan2
- TPH1 | c.1114G>A p.V372I | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.179); catalogued as COSV51459500; called by muse, mutect2, varscan2
- TRIM28 | c.1522G>C p.V508L | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.935); catalogued as COSV53401406; called by muse, mutect2, varscan2
- TRIM47 | c.1786C>T p.R596C | Missense Mutation (SNP) | VAF 43/156 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs768855007, COSV54668868; called by muse, mutect2, varscan2
- TRIM51 | c.1183T>A p.S395T | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1353570885, COSV55269436; called by muse, mutect2, varscan2
- TTC16 | c.131G>T p.S44I | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as COSV58854008; called by muse, mutect2, varscan2
- TTN | c.100450A>G p.T33484A (on ENST00000591111; = p.T26060A on NM_003319.4) | Missense Mutation (SNP) | VAF 94/252 reads (37%) | PolyPhen benign (0.003); catalogued as COSV60243603; called by muse, mutect2, varscan2
- TUBB4A | c.279C>T p.G93= | Splice Region (SNP) | VAF 29/61 reads (48%) | catalogued as COSV51161822; called by muse, mutect2, varscan2
- TUBD1 | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56678661; called by muse, mutect2, varscan2
- UNC13D | c.1216G>A p.G406S | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); catalogued as rs149099554; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VGLL1 | c.367G>T p.A123S | Missense Mutation (SNP) | VAF 82/440 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV65703679; called by muse, mutect2, varscan2
- VTA1 | c.7G>T p.A3S | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.005); catalogued as COSV100859242; called by muse, mutect2, varscan2
- WNT10B | c.391G>T p.A131S | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0.018); catalogued as COSV56406072; called by muse, mutect2, varscan2
- ZBTB18 | c.220G>T p.A74S | Missense Mutation (SNP) | VAF 87/150 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62398140, COSV62398374; called by muse, mutect2, varscan2
- ZCCHC8 | c.1885G>T p.V629F | Missense Mutation (SNP) | VAF 14/264 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as COSV60319400; called by muse, mutect2
- ZFHX4 | c.770C>G p.P257R | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99265984; called by muse, mutect2, varscan2
- ZNF248 | c.1654G>T p.A552S | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.062); catalogued as rs774972023, COSV61998211; called by muse, mutect2, varscan2
- ZNF98 | c.10C>A p.P4T | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV100757478, COSV63338602; called by muse, mutect2, varscan2
- AFF2 | c.1013del p.P338Qfs*11 | Frame Shift Del (DEL) | VAF 11/74 reads (15%) | called by mutect2, pindel, varscan2
- F8 | c.509del p.P170Hfs*15 | Frame Shift Del (DEL) | VAF 58/336 reads (17%) | called by mutect2, pindel, varscan2
- MUC5AC | c.14669G>T p.R4890M | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.944); called by muse, varscan2
- OR51L1 | c.350dup p.L117Ffs*7 | Frame Shift Ins (INS) | VAF 59/191 reads (31%) | called by mutect2, pindel, varscan2
- PCDHB16 | c.1507C>A p.L503M | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, varscan2
- PLEC | c.886_894del p.T296_K298del (on ENST00000322810 / NM_201380.4; = p.T186_K188del on NM_000445.5) | In Frame Del (DEL) | VAF 19/64 reads (30%) | called by mutect2, pindel, varscan2
- ROCK2 | c.4163+1_4163+5del p.X1388_splice | Splice Site (DEL) | VAF 36/135 reads (27%) | called by mutect2, pindel, varscan2
- SFR1 | c.215_217del p.L72_K73delinsQ (on ENST00000369727 / NM_001002759.1; = p.L59_K60delinsQ on NM_145247.4) | In Frame Del (DEL) | VAF 13/89 reads (15%) | called by mutect2, pindel, varscan2
- TCEAL5 | c.566del p.G189Efs*2 | Frame Shift Del (DEL) | VAF 42/188 reads (22%) | called by mutect2, varscan2
- TRAPPC6B | c.445+1del p.X149_splice (on ENST00000330149 / NM_001079537.2; = p.X121_splice on NM_177452.4) | Splice Site (DEL) | VAF 25/236 reads (11%) | called by mutect2, pindel, varscan2
- ABCA12 | c.3246T>A p.A1082= (on ENST00000272895 / NM_173076.3; = p.A764= on NM_015657.3) | Silent (SNP) | VAF 7/86 reads (8%) | catalogued as COSV99791259; called by muse, mutect2
- ACSM2A | c.1341G>A p.R447= (on ENST00000219054; = p.R368= on NM_001308169.2) | Silent (SNP) | VAF 21/122 reads (17%) | catalogued as COSV54588055; called by muse, mutect2, varscan2
- ACSM2B | c.1341G>A p.R447= | Silent (SNP) | VAF 24/352 reads (7%) | catalogued as COSV61657194; called by muse, mutect2
- AFAP1 | c.264C>T p.S88= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as COSV61797684; called by muse, mutect2, varscan2
- AGMO | c.222G>T p.T74= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as COSV61118286, COSV61120470; called by muse, mutect2, varscan2
- BRSK1 | c.1011C>A p.R337= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as COSV58668863; called by muse, mutect2, varscan2
- CEP131 | c.2727C>A p.A909= (on ENST00000269392 / NM_001319228.2; = p.A906= on NM_014984.4) | Silent (SNP) | VAF 14/101 reads (14%) | catalogued as COSV53953457, COSV53955257; called by muse, mutect2, varscan2
- CNR2 | c.150G>A p.E50= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as COSV100991553, COSV65692917; called by muse, mutect2
- CSMD3 | c.3357C>T p.D1119= (on ENST00000297405 / NM_001363185.1; = p.D1015= on NM_052900.3) | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs145905619, COSV52264223; called by muse, mutect2, varscan2
- CTNND2 | c.2049C>A p.T683= | Silent (SNP) | VAF 20/129 reads (16%) | catalogued as COSV58887152; called by muse, mutect2, varscan2
- DBF4B | c.1140C>T p.P380= | Silent (SNP) | VAF 32/192 reads (17%) | catalogued as COSV59262698; called by muse, mutect2, varscan2
- DIP2C | c.3087C>T p.H1029= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as rs758894187, COSV55172515; called by muse, mutect2, varscan2
- DPY19L2 | c.1746C>A p.R582= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV61039920; called by muse, mutect2, varscan2
- GCNA | c.345C>A p.A115= | Silent (SNP) | VAF 40/284 reads (14%) | catalogued as COSV65467798; called by muse, mutect2, varscan2
- GCNA | c.2052G>C p.G684= | Silent (SNP) | VAF 18/134 reads (13%) | catalogued as COSV65462213; called by muse, mutect2, varscan2
- GPR158 | c.3156T>A p.P1052= | Silent (SNP) | VAF 23/111 reads (21%) | catalogued as COSV66278240; called by muse, mutect2, varscan2
- HUWE1 | c.5709A>T p.S1903= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as COSV53358435; called by muse, mutect2, varscan2
- KCNS3 | c.939A>G p.L313= | Silent (SNP) | VAF 18/267 reads (7%) | catalogued as rs1405976706, COSV58408362; called by muse, mutect2
- KLHL13 | c.1506A>G p.Q502= | Silent (SNP) | VAF 33/250 reads (13%) | catalogued as COSV53251398; called by muse, mutect2, varscan2
- KRTAP10-11 | c.795C>A p.S265= | Silent (SNP) | VAF 40/69 reads (58%) | catalogued as rs782693773, COSV58177859, COSV58179059; called by muse, mutect2, varscan2
- MAPKBP1 | c.1662G>T p.G554= (on ENST00000456763 / NM_001128608.2; = p.G548= on NM_014994.3) | Silent (SNP) | VAF 24/97 reads (25%) | catalogued as COSV52965654; called by muse, mutect2, varscan2
- MED24 | c.2220C>T p.G740= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as rs753068864, COSV62420176; called by muse, mutect2, varscan2
- NHSL2 | c.1269C>T p.S423= (on ENST00000510661; = p.S789= on NM_001013627.2) | Silent (SNP) | VAF 7/76 reads (9%) | catalogued as COSV65454445; called by muse, mutect2
- OR4A16 | c.147C>A p.G49= | Silent (SNP) | VAF 51/151 reads (34%) | catalogued as rs779626469, COSV59044574; called by muse, mutect2, varscan2
- OR4C13 | c.753C>A p.P251= | Silent (SNP) | VAF 32/168 reads (19%) | catalogued as COSV73648836, COSV73648861; called by muse, mutect2, varscan2
- PCDHB16 | c.180C>A p.S60= | Silent (SNP) | VAF 7/123 reads (6%) | catalogued as COSV53368167; called by muse, mutect2
- PDHA2 | c.981C>A p.L327= | Silent (SNP) | VAF 38/90 reads (42%) | catalogued as COSV54777119, COSV54780939; called by muse, mutect2, varscan2
- PLEKHG2 | c.516C>T p.A172= | Silent (SNP) | VAF 14/170 reads (8%) | catalogued as rs372499583; called by muse, mutect2
- PPP2R3A | c.1164A>G p.L388= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs767263310, COSV53868562; called by muse, mutect2, varscan2
- PPWD1 | c.1170G>A p.R390= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV54334866; called by muse, mutect2
- PRSS35 | c.762C>A p.V254= | Silent (SNP) | VAF 37/80 reads (46%) | catalogued as COSV63800805, COSV63801027; called by muse, mutect2, varscan2
- PSG8 | c.621C>A p.V207= | Silent (SNP) | VAF 136/314 reads (43%) | catalogued as COSV60614224; called by muse, mutect2, varscan2
- PTPN18 | c.684C>T p.H228= | Silent (SNP) | VAF 30/149 reads (20%) | catalogued as COSV99448010; called by muse, mutect2, varscan2
- RBBP8 | c.2061A>G p.T687= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs766865951, COSV59095099; called by muse, varscan2
- RNF133 | c.873G>T p.G291= | Silent (SNP) | VAF 45/80 reads (56%) | catalogued as COSV57377711; called by muse, mutect2, varscan2
- SH3PXD2B | c.2436G>A p.L812= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as COSV61128868; called by muse, mutect2
- SLC5A2 | c.663C>T p.H221= | Silent (SNP) | VAF 17/107 reads (16%) | catalogued as rs562917404, COSV57893531; called by muse, mutect2, varscan2
- SMCHD1 | c.123G>T p.G41= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV99862239; called by muse, mutect2, varscan2
- SYT13 | c.90T>C p.C30= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV50075649; called by muse, mutect2
- TAS2R16 | c.555G>A p.L185= | Silent (SNP) | VAF 7/118 reads (6%) | catalogued as COSV50798237; called by muse, mutect2
- TCEAL3 | c.336A>G p.R112= | Silent (SNP) | VAF 35/207 reads (17%) | catalogued as COSV54581211; called by muse, mutect2, varscan2
- THBS2 | c.831C>A p.V277= | Silent (SNP) | VAF 16/102 reads (16%) | catalogued as COSV64678505; called by muse, mutect2, varscan2
- TNR | c.1980T>A p.T660= | Silent (SNP) | VAF 16/101 reads (16%) | catalogued as COSV54904524; called by muse, mutect2, varscan2
- CAPN3 | c.380-362G>A | Intron (SNP) | VAF 11/62 reads (18%) | called by muse, mutect2, varscan2
- CFAP61 | c.2503+2305T>G | Intron (SNP) | VAF 32/713 reads (4%) | catalogued as COSV99846038; called by muse, mutect2
- COLEC11 | c.203-11464C>T | Intron (SNP) | VAF 71/258 reads (28%) | catalogued as COSV99363505; called by muse, mutect2, varscan2
- SKP2 | c.*1838G>T | 3'UTR (SNP) | VAF 18/117 reads (15%) | catalogued as COSV57040010, COSV57043817; called by muse, mutect2, varscan2
- TTN | c.10360+3557A>C | Intron (SNP) | VAF 7/81 reads (9%) | catalogued as COSV60243620; called by muse, mutect2
- USP6 | c.1079-158C>A | Intron (SNP) | VAF 9/25 reads (36%) | catalogued as rs757004259, COSV100003836, COSV100004589; called by muse, mutect2, varscan2
